Somatic mutation profile of tumor specimen ALCH-B2YI-TTP1-A (aliquot ALCH-B2YI-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B2YI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 65.0 years (23,745 days).
Specimen ALCH-B2YI-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 480a1267-9f24-411c-9a05-d1d683bc6b31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2YI-NB1-A (Blood Derived Normal), aliquot ALCH-B2YI-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c796e7c-0997-4d04-a47b-8a3602188f42

The open-access MAF lists 1,092 somatic variants for this specimen: 720 protein-altering or splice-affecting, 228 silent, 144 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 616, Silent 228, Intron 62, Nonsense Mutation 57, RNA 31, Splice Site 21, 5'UTR 21, 3'UTR 17, Frame Shift Del 11, Frame Shift Ins 8, 5'Flank 7, 3'Flank 6.

Variants (750 of 1,092; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1715G>A p.C572Y (on ENST00000288602 / NM_001374244.1; = p.C532Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397507479; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD6 | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as rs756642217; called by muse, mutect2
- ACP7 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 90/202 reads (45%) | catalogued as rs1250019430; called by muse, mutect2, varscan2
- ACTR3B | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs1475104354; called by muse, mutect2, varscan2
- ACTRT2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as COSV101007529; called by muse, mutect2, varscan2
- ADGRB1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as COSV60103195; called by muse, mutect2, varscan2
- ADGRV1 | c.13937C>T p.P4646L | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV67981659, COSV67987329; called by muse, mutect2, varscan2
- AGAP1 | c.1549G>C p.D517H (on ENST00000304032 / NM_001037131.3; = p.D464H on NM_014914.5) | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs763938420; called by muse, mutect2, varscan2
- AHNAK2 | c.3781C>A p.L1261I | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as rs765839118; called by muse, mutect2, varscan2
- ALMS1 | c.6194G>C p.R2065T | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV52518547; called by muse, mutect2, varscan2
- AMY1A | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 108/1192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756917279; called by muse, mutect2, varscan2
- ANK2 | c.6956C>T p.T2319I | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs762042163; called by muse, mutect2, varscan2
- ANKRD1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 113/594 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs774406553; called by muse, mutect2, varscan2
- AP4M1 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 185/750 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs201580004; called by muse, varscan2
- ARFGAP1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 136/563 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV62262766; called by muse, mutect2, varscan2
- ARHGAP30 | c.2782C>G p.L928V (on ENST00000368013 / NM_001025598.2; = p.L717V on NM_181720.3) | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63514846; called by muse, mutect2
- ASCC2 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 113/440 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1382957621; called by muse, mutect2, varscan2
- ATP6V1B1 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.137); catalogued as COSV52266653; called by mutect2, varscan2
- B2M | c.258C>A p.Y86* | Nonsense Mutation (SNP) | VAF 115/380 reads (30%) | catalogued as COSV62565389, COSV62565714; called by muse, mutect2, varscan2
- B4GALNT4 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs889638678; called by muse, mutect2, varscan2
- BCAN | c.2551C>A p.R851S | Missense Mutation (SNP) | VAF 100/473 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749535108, COSV100228391; called by muse, mutect2, varscan2
- BCHE | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 151/509 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV52253812; called by muse, mutect2, varscan2
- BCR | c.1051A>T p.S351C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs745787464; called by muse, mutect2, varscan2
- BNC2 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101033662; called by muse, mutect2, varscan2
- BRINP3 | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66538197; called by muse, mutect2, varscan2
- BSN | c.6394G>T p.G2132W | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs201714007, COSV56513098; called by muse, mutect2, varscan2
- C1orf94 | c.1599C>G p.I533M (on ENST00000488417 / NM_001134734.2; = p.I343M on NM_032884.5) | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV64915441; called by muse, mutect2, varscan2
- CAPN14 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101294799; called by muse, mutect2, varscan2
- CBLL2 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100081486; called by muse, mutect2, varscan2
- CCDC136 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | catalogued as COSV52800711; called by muse, mutect2, varscan2
- CCDC168 | c.10231A>T p.K3411* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | catalogued as COSV59421905; called by muse, varscan2
- CCDC171 | c.1227C>G p.H409Q | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as rs376647184; called by muse, mutect2, varscan2
- CCKBR | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs200262698, COSV58099916; called by muse, mutect2, varscan2
- CDH11 | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs373083222; called by muse, mutect2, varscan2
- CDH16 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 88/526 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as COSV55340400; called by muse, mutect2, varscan2
- CDH23 | c.1449G>C p.L483= | Splice Region (SNP) | VAF 108/494 reads (22%) | catalogued as rs368830397; called by muse, mutect2, varscan2
- CDHR2 | c.1637T>A p.L546Q | Missense Mutation (SNP) | VAF 152/628 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56146146; called by muse, mutect2, varscan2
- CENPE | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54382834; called by muse, mutect2, varscan2
- CEP162 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV57618626; called by muse, mutect2, varscan2
- CLCA1 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 82/856 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs765135691; called by muse, mutect2
- CLSPN | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs368555540; called by muse, mutect2, varscan2
- CNBD1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 53/349 reads (15%) | catalogued as COSV73072488; called by muse, mutect2, varscan2
- CNDP1 | c.1473G>C p.E491D | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1412978199, COSV100722216; called by muse, mutect2, varscan2
- COL2A1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 143/625 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM074103; called by muse, mutect2, varscan2
- COL5A3 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99318980; called by muse, mutect2, varscan2
- CRISP2 | c.270C>A p.T90= | Splice Region (SNP) | VAF 98/371 reads (26%) | catalogued as COSV100189229; called by muse, mutect2, varscan2
- CSMD3 | c.8912G>T p.G2971V (on ENST00000297405 / NM_001363185.1; = p.G2802V on NM_052900.3) | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52134630; called by muse, mutect2, varscan2
- CSMD3 | c.6800G>T p.G2267V (on ENST00000297405 / NM_001363185.1; = p.G2163V on NM_052900.3) | Missense Mutation (SNP) | VAF 65/617 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99834367; called by muse, mutect2, varscan2
- CSMD3 | c.6259C>T p.H2087Y (on ENST00000297405 / NM_001363185.1; = p.H1983Y on NM_052900.3) | Missense Mutation (SNP) | VAF 74/473 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV52165371; called by muse, mutect2, varscan2
- CUBN | c.3519C>A p.S1173R | Missense Mutation (SNP) | VAF 143/646 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs369192214, COSV64720040; called by muse, mutect2, varscan2
- CUEDC1 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 121/469 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as COSV64226889; called by muse, mutect2, varscan2
- CWH43 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56938070; called by muse, mutect2, varscan2
- CYLC2 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 136/433 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs1436809957; called by muse, mutect2, varscan2
- CYTH4 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs200267703, COSV50632119; called by muse, mutect2
- DDX28 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 108/510 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1319479022; called by muse, mutect2, varscan2
- DEAF1 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 110/504 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99448553; called by muse, mutect2, varscan2
- DMXL1 | c.4864A>G p.I1622V | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.463); catalogued as rs756926268; called by muse, mutect2, varscan2
- DNAH11 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60984748; called by muse, mutect2, varscan2
- DNAI4 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1163894613; called by muse, mutect2, varscan2
- DNAJC11 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 79/284 reads (28%) | catalogued as COSV99037354; called by muse, mutect2, varscan2
- DST | c.20954C>T p.T6985M (on ENST00000361203 / NM_001374722.1; = p.T4682M on NM_015548.5) | Missense Mutation (SNP) | VAF 59/535 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1311125208; called by muse, mutect2, varscan2
- DST | c.4159C>T p.R1387* (on ENST00000361203 / NM_001374722.1; = p.R1061* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 161/744 reads (22%) | catalogued as COSV99056234; called by muse, mutect2, varscan2
- EGFL8 | c.485C>G p.T162R | Missense Mutation (SNP) | VAF 105/540 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61248042; called by muse, mutect2, varscan2
- EPHB1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67668915; called by muse, mutect2, varscan2
- ERBB4 | c.2323A>G p.M775V | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781737887, COSV61503151; called by muse, mutect2, varscan2
- ERCC6 | c.3911G>T p.C1304F | Missense Mutation (SNP) | VAF 265/1019 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1173513523; called by muse, mutect2, varscan2
- ETNPPL | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs772650876, COSV56595837; called by muse, mutect2, varscan2
- EVC2 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1003376249; called by muse, mutect2, varscan2
- FAM111B | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs573535193; called by muse, mutect2, varscan2
- FAM189A1 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV54271446; called by muse, mutect2, varscan2
- FAM47C | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 133/256 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs782084099; called by muse, mutect2, varscan2
- FAM53C | c.1099G>C p.G367R | Missense Mutation (SNP) | VAF 111/551 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs765733710; called by muse, mutect2, varscan2
- FAM83B | c.1580A>T p.E527V | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV60919231; called by muse, mutect2, varscan2
- FAN1 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs751203175; called by muse, mutect2, varscan2
- FBN2 | c.5963G>T p.G1988V | Missense Mutation (SNP) | VAF 149/730 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52508080; called by muse, mutect2, varscan2
- FGD5 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV53242431; called by muse, mutect2, varscan2
- FGFR4 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52801313; called by muse, mutect2, varscan2
- FLG2 | c.5096C>A p.T1699K | Missense Mutation (SNP) | VAF 126/548 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV101166254; called by muse, mutect2, varscan2
- FMN2 | c.3613G>T p.G1205W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60430384; called by muse, mutect2, varscan2
- FOXA2 | c.433G>A p.A145T (on ENST00000377115 / NM_153675.3; = p.A151T on NM_021784.5) | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV101008374; called by muse, mutect2, varscan2
- FOXG1 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 276/1202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57399444; called by muse, mutect2, varscan2
- FRMPD4 | c.3732del p.K1245Sfs*3 | Frame Shift Del (DEL) | VAF 39/107 reads (36%) | catalogued as COSV66212843; called by mutect2, pindel, varscan2
- GJA8 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs782294604, COSV99569415; called by muse, mutect2, varscan2
- GPC6 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 84/254 reads (33%) | catalogued as COSV65530559; called by muse, mutect2, varscan2
- GPR148 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59309825; called by muse, mutect2, varscan2
- GRM7 | c.2698+1G>T p.X900_splice | Splice Site (SNP) | VAF 64/239 reads (27%) | catalogued as COSV63129570; called by muse, mutect2
- H1-6 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 136/672 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV58089898; called by muse, mutect2, varscan2
- HEATR3 | c.527G>T p.R176I | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs747648735; called by muse, mutect2, varscan2
- HEPACAM2 | c.838T>A p.Y280N (on ENST00000394468 / NM_001039372.4; = p.Y268N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/391 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59061092; called by muse, mutect2, varscan2
- HNRNPAB | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs748717355, COSV57424248; called by muse, mutect2, varscan2
- IGFN1 | c.2347C>A p.R783S (on ENST00000295591 / NM_001367841.1; = p.R3240S on NM_001164586.2) | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs540656699; called by muse, mutect2, varscan2
- KANK4 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1390022806, COSV58093929; called by muse, mutect2, varscan2
- KCNMA1 | c.2077T>A p.C693S | Missense Mutation (SNP) | VAF 135/628 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV54243633; called by mutect2, varscan2
- KERA | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 71/272 reads (26%) | catalogued as COSV99899310; called by muse, mutect2, varscan2
- KIF21A | c.4660G>A p.D1554N (on ENST00000361418 / NM_001378440.1; = p.D1541N on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs775761627; called by muse, mutect2, varscan2
- KIF26B | c.5401C>A p.L1801M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV63638504; called by muse, mutect2, varscan2
- KIF5A | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 247/1086 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.552); catalogued as COSV99672903; called by muse, mutect2, varscan2
- KRTAP6-2 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 65/151 reads (43%) | PolyPhen benign (0.087); catalogued as COSV100588918; called by muse, mutect2, varscan2
- LEFTY2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as rs762606282; called by muse, mutect2, varscan2
- LILRA1 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 144/522 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs780771279; called by muse, varscan2
- LRRC74A | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53612733; called by muse, mutect2, varscan2
- LRRN4CL | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99042307; called by muse, mutect2, varscan2
- LSAMP | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 30/156 reads (19%) | catalogued as rs1196891684; called by muse, mutect2, varscan2
- MACC1 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs767450824; called by muse, mutect2, varscan2
- MAGEA4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99367342; called by muse, mutect2, varscan2
- MAP3K21 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV64043465, COSV64044504; called by muse, mutect2, varscan2
- MBTPS1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751490114; called by muse, mutect2, varscan2
- MECOM | c.2227C>T p.P743S (on ENST00000468789 / NM_001105078.4; = p.P931S on NM_004991.4) | Missense Mutation (SNP) | VAF 132/698 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV52973118; called by muse, mutect2, varscan2
- MFN1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV54937846; called by muse, mutect2, varscan2
- MS4A10 | c.135C>G p.H45Q | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs775242233; called by muse, mutect2, varscan2
- MTARC1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1284276924; called by muse, mutect2, varscan2
- MUC16 | c.36919G>A p.D12307N | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.245); catalogued as rs773389232; called by muse, mutect2, varscan2
- MUC5AC | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 115/456 reads (25%) | SIFT deleterious (0); catalogued as COSV100650732; called by muse, mutect2, varscan2
- MVP | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753554076, COSV100651458, COSV62421507; called by muse, mutect2, varscan2
- MYH15 | c.2353C>A p.L785M | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56310850; called by muse, mutect2, varscan2
- MYOD1 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100000133; called by muse, mutect2, varscan2
- MYOM3 | c.2491G>T p.G831W | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100293961; called by muse, mutect2, varscan2
- MYT1L | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV67727867; called by muse, mutect2, varscan2
- NEUROD1 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 61/471 reads (13%) | catalogued as COSV54548731; called by muse, mutect2, varscan2
- NIN | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 174/950 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV55392062, COSV55399618, COSV99813728; called by muse, mutect2, varscan2
- NOTCH1 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53036368, COSV53074230, COSV99488292; called by muse, mutect2, varscan2
- NRXN1 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 36/211 reads (17%) | catalogued as COSV60520265; called by muse, mutect2, varscan2
- NUAK1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 108/453 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99776927; called by muse, mutect2, varscan2
- NUP210 | c.3817G>C p.E1273Q | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54402463; called by muse, mutect2, varscan2
- OLFML2B | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54196864; called by muse, varscan2
- OR10K2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319986373; called by muse, mutect2, varscan2
- OR10R2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63768465; called by muse, mutect2, varscan2
- OR13F1 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100594711; called by muse, mutect2, varscan2
- OR14C36 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 124/404 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58602621; called by muse, mutect2, varscan2
- OR4A15 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 97/426 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59033435, COSV59036307; called by muse, mutect2, varscan2
- OR4K5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 105/1302 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100262525, COSV60002621; called by muse, mutect2
- OR4Q3 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100057056, COSV59180444; called by muse, mutect2
- OR51E1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760647045, COSV67809478, COSV67810339; called by muse, mutect2, varscan2
- OR51G2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV58992320; called by muse, mutect2, varscan2
- OR5AS1 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 94/390 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57981224; called by muse, mutect2, varscan2
- OR6X1 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60009614; called by muse, mutect2, varscan2
- OR8H2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs777087856, COSV57944234; called by muse, mutect2, varscan2
- OR8K3 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV57130989; called by muse, mutect2, varscan2
- OR9Q1 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100109449; called by muse, mutect2, varscan2
- OTOL1 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV60006876; called by muse, mutect2, varscan2
- OVCH1 | c.2413G>T p.D805Y | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100548178; called by muse, varscan2
- P2RY12 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1157349113, COSV99043974; called by muse, mutect2, varscan2
- PCDHB2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52032400; called by muse, mutect2, varscan2
- PEAK1 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.598); catalogued as rs1160892253; called by muse, mutect2, varscan2
- PEAR1 | c.1898C>G p.S633W | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52774151, COSV52775148; called by muse, mutect2, varscan2
- PELI2 | c.310-2A>T p.X104_splice | Splice Site (SNP) | VAF 57/278 reads (21%) | catalogued as COSV50710064; called by muse, mutect2, varscan2
- PHC2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1325007745; called by muse, mutect2
- PLOD3 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99778100; called by muse, mutect2, varscan2
- PLXNA4 | c.3301C>A p.L1101I | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.196); catalogued as COSV58167002; called by muse, mutect2, varscan2
- PNPLA8 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV57551427; called by muse, mutect2, varscan2
- PNPT1 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 69/345 reads (20%) | catalogued as COSV53175998, COSV53180427; called by muse, mutect2, varscan2
- POLR3A | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 144/722 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965573; called by muse, mutect2, varscan2
- POTEC | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 50/618 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs149536586, COSV100743692, COSV62804206; called by muse, mutect2
- POU6F2 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 125/713 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.121); catalogued as rs768295622; called by muse, mutect2, varscan2
- PPP1R2B | c.226C>G p.H76D | Missense Mutation (SNP) | VAF 252/1031 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV70372692; called by muse, mutect2, varscan2
- PRRC2A | c.3205G>T p.G1069W | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV65688465; called by muse, mutect2, varscan2
- PRRC2A | c.4510C>T p.P1504S | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs752771546; called by muse, mutect2, varscan2
- RB1 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 59/261 reads (23%) | catalogued as CM063089, COSV57318387; called by muse, mutect2, varscan2
- RELB | c.1277-6C>T | Splice Region (SNP) | VAF 118/223 reads (53%) | catalogued as rs1202582355; called by muse, mutect2, varscan2
- RESF1 | c.2366A>G p.Y789C | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771188313; called by muse, mutect2, varscan2
- RGS19 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58659269; called by muse, mutect2, varscan2
- RHNO1 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs762715723; called by muse, mutect2, varscan2
- RIMBP2 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs748503695, COSV55476695; called by muse, varscan2
- RIMS2 | c.4681C>A p.P1561T (on ENST00000666250 / NM_001348490.2; = p.P1132T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/1096 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV99169604; called by muse, mutect2, varscan2
- RIOK2 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 242/1012 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51612062; called by muse, mutect2, varscan2
- RTN4RL2 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58653201; called by muse, varscan2
- RYR2 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63713727; called by muse, mutect2, varscan2
- RYR2 | c.3823G>A p.G1275S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs769294223, COSV63657293, COSV63684336; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.12464C>T p.S4155F | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as CM1310852, COSV63664208; called by muse, mutect2, varscan2
- SAMD4A | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 208/982 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51884746; called by muse, mutect2, varscan2
- SAMD9L | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59080488; called by muse, mutect2, varscan2
- SCAF4 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1366742307, COSV54589014; called by muse, mutect2
- SCGB1D2 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs774070276; called by muse, mutect2, varscan2
- SCN5A | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM030950; called by muse, mutect2, varscan2
- SEMA5A | c.2920G>T p.V974L | Missense Mutation (SNP) | VAF 115/577 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs529504980, COSV66807638; called by muse, varscan2
- SERPINA6 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 203/783 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1052759090; called by muse, mutect2, varscan2
- SIPA1L2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53394455, COSV99477123; called by muse, mutect2, varscan2
- SLC26A7 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 52/530 reads (10%) | catalogued as COSV52591621; called by muse, mutect2
- SLIT3 | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 95/437 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60616113; called by muse, mutect2, varscan2
- SLITRK6 | c.1288A>T p.M430L | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1360877413, COSV68389624; called by muse, varscan2
- SNRNP40 | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 40/122 reads (33%) | catalogued as COSV99745428; called by muse, mutect2
- SPATA31A1 | c.3290G>T p.C1097F | Missense Mutation (SNP) | VAF 275/1238 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV66533446; called by muse, mutect2, varscan2
- SPATA31A7 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs1418163528; called by mutect2, varscan2
- SPOP | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61655149; called by muse, mutect2, varscan2
- ST18 | c.55+1G>A p.X19_splice | Splice Site (SNP) | VAF 109/504 reads (22%) | catalogued as COSV99388541; called by muse, mutect2, varscan2
- STS | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV54272567; called by muse, mutect2, varscan2
- SULF1 | c.1191-1G>C p.X397_splice | Splice Site (SNP) | VAF 96/410 reads (23%) | catalogued as COSV52689167; called by muse, mutect2, varscan2
- SV2C | c.1817G>T p.R606I | Missense Mutation (SNP) | VAF 86/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59219433; called by muse, mutect2, varscan2
- SYT8 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99425262; called by muse, mutect2, varscan2
- SZT2 | c.4795G>T p.E1599* (on ENST00000634258 / NM_001365999.1; = p.E1542* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100987699; called by muse, mutect2, varscan2
- TAFA3 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV62624980; called by muse, mutect2, varscan2
- TAS2R16 | c.357G>T p.R119S | Missense Mutation (SNP) | VAF 122/563 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99972162; called by muse, mutect2, varscan2
- TBC1D7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as COSV100568548; called by muse, mutect2, varscan2
- TECTA | c.714C>A p.N238K | Missense Mutation (SNP) | VAF 217/725 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs148478527; called by muse, mutect2, varscan2
- TENM4 | c.2505G>T p.E835D | Missense Mutation (SNP) | VAF 246/625 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV53629734; called by muse, mutect2, varscan2
- TET2 | c.5633G>T p.R1878L | Missense Mutation (SNP) | VAF 59/428 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV54439835; called by muse, mutect2, varscan2
- TINAGL1 | c.1200C>G p.H400Q | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54700159; called by muse, mutect2, varscan2
- TLR4 | c.585G>T p.L195F (on ENST00000355622 / NM_138554.5; = p.L155F on NM_003266.4) | Missense Mutation (SNP) | VAF 134/519 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs763846185; called by muse, mutect2, varscan2
- TMEM132C | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.31); catalogued as rs1321084991, COSV101473456; called by muse, mutect2, varscan2
- TMEM229A | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1423690000; called by muse, mutect2, varscan2
- TMTC1 | c.616C>A p.L206M (on ENST00000539277 / NM_001193451.2; = p.L98M on NM_175861.3) | Missense Mutation (SNP) | VAF 128/614 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV55480192; called by muse, mutect2, varscan2
- TNFSF14 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55591388; called by muse, mutect2
- TP53 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TPSAB1 | c.225C>A p.C75* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs370737397, COSV58782384; called by muse, mutect2, varscan2
- TRIM49B | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 102/493 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs564111008, COSV60319932; called by muse, mutect2, varscan2
- TRIO | c.4115G>T p.C1372F | Missense Mutation (SNP) | VAF 52/503 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60087526; called by muse, mutect2
- TRPV6 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63890965; called by muse, mutect2, varscan2
- TSHZ3 | c.1812G>T p.K604N | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99552695; called by muse, mutect2, varscan2
- TSPAN19 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs1439264737, COSV70814227; called by muse, mutect2, varscan2
- TTC27 | c.2339G>T p.S780I | Missense Mutation (SNP) | VAF 69/537 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1175571803; called by muse, mutect2, varscan2
- TYR | c.756G>T p.M252I | Missense Mutation (SNP) | VAF 297/437 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV54470520; called by muse, mutect2, varscan2
- UGT2B28 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100159056; called by muse, mutect2, varscan2
- UGT2B7 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 160/693 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs147176472; called by muse, mutect2, varscan2
- UNC5A | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52837577; called by muse, mutect2, varscan2
- USH2A | c.2050C>G p.Q684E | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV100244562; called by muse, mutect2, varscan2
- USP6NL | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 130/742 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99509509; called by muse, varscan2
- VCX | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 92/1022 reads (9%) | catalogued as rs866333594; called by muse, varscan2
- VLDLR | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM134781; called by muse, mutect2, varscan2
- VWF | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 182/799 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54614085; called by muse, mutect2, varscan2
- WNT9B | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV51518015; called by muse, mutect2, varscan2
- XIRP1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 72/477 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760310458; called by muse, mutect2, varscan2
- ZACN | c.568del p.H190Tfs*3 | Frame Shift Del (DEL) | VAF 52/264 reads (20%) | catalogued as rs758213401; called by mutect2, pindel, varscan2
- ZAR1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs763483115; called by muse, mutect2, varscan2
- ZNF330 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV53707168; called by muse, mutect2, varscan2
- ZNF679 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV55380775; called by muse, mutect2, varscan2
- ZNF729 | c.991C>A p.H331N | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.53); catalogued as rs1568577140; called by muse, mutect2, varscan2
- ZNF729 | c.2301G>T p.L767F | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV62606914; called by muse, mutect2, varscan2
- ABCA13 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 85/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABCA13 | c.6182A>T p.K2061M | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABCB5 | c.2987C>A p.P996Q (on ENST00000404938 / NM_001163941.2; = p.P551Q on NM_178559.6) | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCC4 | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ABCD1 | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABRAXAS2 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN3 | c.263-1G>T p.X88_splice | Splice Site (SNP) | VAF 60/252 reads (24%) | called by muse, varscan2
- ADAMTS12 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.2927A>T p.D976V | Missense Mutation (SNP) | VAF 127/873 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADAMTS9 | c.1745T>A p.M582K | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY7 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ADCY8 | c.3580G>T p.A1194S | Missense Mutation (SNP) | VAF 171/407 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ADGRA1 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRB3 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.3288G>T p.M1096I | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ADGRG2 | c.2622C>A p.F874L (on ENST00000379869 / NM_001079858.3; = p.F871L on NM_005756.4) | Missense Mutation (SNP) | VAF 133/258 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ADI1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ADRA1A | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL4 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 59/525 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- AGPAT4 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AHNAK | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.929); called by muse, mutect2
- AIP | c.523A>T p.K175* | Nonsense Mutation (SNP) | VAF 55/509 reads (11%) | called by muse, mutect2, varscan2
- AKR7L | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.5740A>G p.T1914A | Missense Mutation (SNP) | VAF 52/510 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2
- ALPK1 | c.929A>T p.Y310F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMHR2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 192/913 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMOT | c.1347G>T p.R449S (on ENST00000371959 / NM_001113490.1; = p.R40S on NM_133265.3) | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- AMPH | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- AMZ1 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ANK1 | c.1998+1G>T p.X666_splice | Splice Site (SNP) | VAF 55/448 reads (12%) | called by muse, mutect2, varscan2
- ANKLE2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ANKRD30B | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ANKRD30B | c.1368A>T p.L456F | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ANKRD33B | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANO1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 84/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANO2 | c.1954T>A p.Y652N (on ENST00000356134 / NM_001278597.3; = p.Y656N on NM_001278596.3) | Missense Mutation (SNP) | VAF 136/595 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP2A2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, varscan2
- AP3D1 | c.1159del p.A387Qfs*39 | Frame Shift Del (DEL) | VAF 67/290 reads (23%) | called by mutect2, pindel, varscan2
- ARC | c.377G>C p.W126S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ARFGAP1 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ARNT | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASTN2 | c.1335C>A p.C445* (on ENST00000313400 / NM_001365069.1; = p.C394* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 81/288 reads (28%) | called by muse, mutect2, varscan2
- ATP5ME | c.192T>A p.D64E | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP6V1B1 | c.98dup p.Y33* | Nonsense Mutation (INS) | VAF 22/201 reads (11%) | called by mutect2, varscan2
- B3GALT5 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.847); called by muse, varscan2
- B3GNT5 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- BACH2 | c.1961G>C p.S654T | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- BCAS3 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- BLID | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 80/503 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- BPTF | c.2076G>C p.E692D | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BRCC3 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BSN | c.9703G>T p.D3235Y | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- BTN3A3 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 194/788 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTRC | c.245G>T p.S82I (on ENST00000370187 / NM_033637.4; = p.S46I on NM_003939.5) | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C18orf63 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- C1R | c.58C>A p.L20I (on ENST00000536053 / NM_001354346.2; = p.L6I on NM_001733.7) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- C3AR1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf49 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CACNA1C | c.6415G>C p.D2139H (on ENST00000399634 / NM_001167625.1; = p.D2068H on NM_000719.7) | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNA1E | c.5531C>A p.P1844H | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CAPRIN1 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC114 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CCDC168 | c.10136G>T p.S3379I | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, varscan2
- CCDC39 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- CCDC63 | c.1268G>T p.C423F | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CCR5 | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CD207 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 55/503 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CDC42EP4 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CDH16 | c.2128C>A p.P710T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CDH17 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 135/367 reads (37%) | called by muse, mutect2, varscan2
- CDH26 | c.2447C>T p.S816L (on ENST00000348616 / NM_177980.4; = p.S149L on NM_021810.6) | Missense Mutation (SNP) | VAF 170/638 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDH5 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 154/754 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CENPE | c.5304+1G>T p.X1768_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- CEP41 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 151/693 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CEP63 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 245/1126 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CFAP61 | c.1578C>G p.I526M | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CFHR4 | c.1382C>A p.P461Q (on ENST00000367416 / NM_001201551.2; = p.P215Q on NM_006684.5) | Missense Mutation (SNP) | VAF 66/856 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CFHR4 | c.1384C>A p.P462T (on ENST00000367416 / NM_001201551.2; = p.P216T on NM_006684.5) | Missense Mutation (SNP) | VAF 70/879 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.224); called by muse, mutect2
- CFHR5 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CGA | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 124/434 reads (29%) | called by muse, varscan2
- CHGB | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 56/530 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2
- CIAO3 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CKM | c.194-1G>T p.X65_splice | Splice Site (SNP) | VAF 75/143 reads (52%) | called by muse, mutect2, varscan2
- CLCN3 | c.25A>T p.R9* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- CLDN17 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLIP3 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CLSTN2 | c.2419C>A p.Q807K | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CNBD1 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COBL | c.2892G>T p.Q964H | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL27A1 | c.4087C>A p.P1363T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- COL3A1 | c.2900C>A p.P967H | Missense Mutation (SNP) | VAF 113/386 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- COL5A3 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL6A2 | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 154/544 reads (28%) | called by muse, mutect2, varscan2
- CORO1A | c.1012T>C p.Y338H | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CORO2B | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- COX11 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- COX5B | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 90/651 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACD | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 170/705 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CSMD1 | c.5526+1G>T p.X1842_splice (on ENST00000520002; = p.X1841_splice on NM_033225.6) | Splice Site (SNP) | VAF 22/74 reads (30%) | called by muse, varscan2
- CSMD3 | c.3364C>A p.L1122M (on ENST00000297405 / NM_001363185.1; = p.L1018M on NM_052900.3) | Missense Mutation (SNP) | VAF 44/503 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CUL3 | c.1614C>G p.F538L | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CWH43 | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CYP2C18 | c.169-1G>T p.X57_splice | Splice Site (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2
- CYP8B1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DACT2 | c.1631dup p.G545Rfs*19 | Frame Shift Ins (INS) | VAF 20/59 reads (34%) | called by mutect2, pindel
- DALRD3 | c.976C>G p.L326V (on ENST00000341949 / NM_001009996.3; = p.L159V on NM_018114.5) | Missense Mutation (SNP) | VAF 57/422 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DAP3 | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DCDC1 | c.4057C>G p.Q1353E (on ENST00000597505 / NM_001367979.1; = p.Q460E on NM_020869.3) | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCHS1 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, varscan2
- DCLK1 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- DDIAS | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DDX53 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DDX60L | c.3881A>T p.D1294V | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- DEFB114 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- DENND2A | c.1463A>G p.N488S | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- DGKB | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DHFR2 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 161/747 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DIP2C | c.3495G>C p.K1165N | Missense Mutation (SNP) | VAF 94/504 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DISP3 | c.2685G>T p.Q895H | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DIXDC1 | c.1965A>T p.K655N (on ENST00000440460 / NM_001037954.4; = p.K444N on NM_033425.4) | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- DMWD | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DMXL1 | c.1585A>T p.R529* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- DNAH1 | c.5267G>C p.R1756T | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.8118C>A p.Y2706* | Nonsense Mutation (SNP) | VAF 70/277 reads (25%) | called by muse, mutect2, varscan2
- DNAH12 | c.4468G>A p.D1490N (on ENST00000351747; = p.D1513N on NM_001366028.2) | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH14 | c.5898G>T p.W1966C (on ENST00000445597; = p.W2506C on NM_001367479.1) | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH9 | c.6097C>T p.L2033F | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB8 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJC13 | c.5479C>A p.P1827T | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DNAJC21 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAJC21 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DNAJC8 | c.510dup p.A171Cfs*6 | Frame Shift Ins (INS) | VAF 82/311 reads (26%) | called by mutect2, pindel, varscan2
- DNASE2B | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DNM3 | c.1628G>T p.G543V (on ENST00000355305 / NM_001350206.2; = p.G533V on NM_015569.5) | Missense Mutation (SNP) | VAF 211/884 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMT3A | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK10 | c.4393+1G>T p.X1465_splice | Splice Site (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2
- DPP10 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 48/332 reads (14%) | called by muse, varscan2
- DYNC1H1 | c.5446G>C p.V1816L | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- EBF3 | c.879dup p.V294Sfs*56 (on ENST00000355311 / NM_001375392.1; = p.V285Sfs*56 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 105/458 reads (23%) | called by mutect2, pindel, varscan2
- EFCAB12 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 129/565 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHHADH | c.1388C>G p.S463* | Nonsense Mutation (SNP) | VAF 30/196 reads (15%) | called by muse, varscan2
- EIF2B4 | c.1564G>A p.D522N (on ENST00000347454 / NM_001034116.2; = p.D521N on NM_015636.3) | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EIF3A | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 145/680 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ELP4 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- ELP4 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 38/213 reads (18%) | called by muse, varscan2
- EML6 | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 130/489 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EPHA3 | c.2243C>A p.A748D | Missense Mutation (SNP) | VAF 116/530 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB6 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- EPS15L1 | c.825C>G p.D275E | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- EPS8L2 | c.1815G>T p.R605S | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ERC1 | c.2521G>A p.E841K (on ENST00000360905 / NM_178040.4; = p.E813K on NM_178039.4) | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ERCC6 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- EREG | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- ESPL1 | c.4069G>T p.G1357C | Missense Mutation (SNP) | VAF 99/438 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ETNPPL | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 73/541 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EYS | c.3707G>C p.C1236S | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- FAM133A | c.226dup p.S76Kfs*10 | Frame Shift Ins (INS) | VAF 42/101 reads (42%) | called by mutect2, pindel, varscan2
- FAM135B | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM171A2 | c.2045C>A p.T682N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM216B | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- FAM71F1 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FBXO11 | c.2116G>C p.D706H (on ENST00000403359 / NM_001190274.2; = p.D622H on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FBXO48 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- FGF20 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FLG | c.2315A>C p.Q772P | Missense Mutation (SNP) | VAF 267/904 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.447dup p.K150Efs*4 | Frame Shift Ins (INS) | VAF 340/1413 reads (24%) | called by mutect2, pindel, varscan2
- FMN2 | c.3614G>T p.G1205V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FMO4 | c.1323A>G p.I441M | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- FOXI1 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GALNT18 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GALNT5 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 146/545 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- GDF10 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GEMIN5 | c.818G>T p.R273I | Missense Mutation (SNP) | VAF 96/501 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLI1 | c.2776C>A p.Q926K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GNG2 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GNS | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 80/802 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2
- GOLGB1 | c.3295C>G p.Q1099E | Missense Mutation (SNP) | VAF 155/864 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GPATCH2 | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- GPATCH8 | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPR101 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GPR143 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- GPR179 | c.1605C>G p.F535L (on ENST00000621958; = p.F534L on NM_001004334.4) | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR26 | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRIN3 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 73/428 reads (17%) | called by muse, mutect2, varscan2
- GPT2 | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRAP2 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA2 | c.225T>A p.N75K | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.77); called by muse, mutect2
- GRM8 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GTF3C1 | c.3628A>T p.R1210W | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- GYG2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- HACD1 | c.34A>C p.S12R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HEATR1 | c.2500G>C p.E834Q | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- HECTD4 | c.13135A>G p.I4379V | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HECW1 | c.2029T>A p.C677S | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HENMT1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 68/227 reads (30%) | called by muse, mutect2, varscan2
- HERC1 | c.9870+1del p.X3290_splice | Splice Site (DEL) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- HERC6 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HIGD2B | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 126/437 reads (29%) | called by muse, mutect2, varscan2
- HIVEP3 | c.3117G>C p.E1039D | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HMCN1 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 54/563 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.606); called by muse, mutect2
- HMCN1 | c.10936G>T p.D3646Y | Missense Mutation (SNP) | VAF 174/705 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGCS2 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 91/694 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA11 | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 256/1214 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD13 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- HRH2 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 98/433 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HSF5 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 140/653 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.14616C>A p.D4872E | Missense Mutation (SNP) | VAF 98/412 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IFT140 | c.2769-2A>T p.X923_splice | Splice Site (SNP) | VAF 73/220 reads (33%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 67/634 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGLV2-14 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 95/350 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IL17A | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 72/595 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IMPG1 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- IMPG1 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQGAP2 | c.1188C>A p.S396R | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ITIH2 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KAZN | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 86/269 reads (32%) | called by muse, mutect2, varscan2
- KCNA1 | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KCNC2 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 127/529 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCNK10 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KCNQ5 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.484); called by muse, mutect2
- KEAP1 | c.1116_1136del p.L373_G379del | In Frame Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- KIF26A | c.3145G>A p.G1049R | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KLC1 | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 104/501 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); called by muse, varscan2
- KLHL2 | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KLHL2 | c.1139G>T p.W380L | Missense Mutation (SNP) | VAF 117/939 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL2 | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 121/940 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.4782G>C p.E1594D | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KMT2C | c.2276C>A p.S759Y | Missense Mutation (SNP) | VAF 87/474 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- KRTAP2-4 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- LAMA1 | c.6161A>T p.H2054L | Missense Mutation (SNP) | VAF 253/744 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LAMA1 | c.910T>A p.C304S | Missense Mutation (SNP) | VAF 242/722 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, varscan2
- LAMA2 | c.1499G>T p.C500F | Missense Mutation (SNP) | VAF 189/634 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMTOR3 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LCE1F | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LCMT2 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.148); called by muse, mutect2
- LHX8 | c.1035_1036delinsA p.H346Ifs*3 | Frame Shift Del (DEL) | VAF 67/606 reads (11%) | called by pindel, varscan2*
- LPP | c.108_109del p.S37Yfs*17 | Frame Shift Del (DEL) | VAF 56/390 reads (14%) | called by pindel, varscan2
- LRFN5 | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LRP1 | c.12224A>G p.N4075S | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- LRP1B | c.4058A>C p.D1353A | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRP2 | c.4615G>C p.D1539H | Missense Mutation (SNP) | VAF 55/471 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC9 | c.3848G>A p.R1283K | Missense Mutation (SNP) | VAF 80/427 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, varscan2
- LY6G6F | c.870-2A>T p.X290_splice | Splice Site (SNP) | VAF 115/553 reads (21%) | called by muse, mutect2, varscan2
- LZTR1 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- MAGEA4 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MAGEB5 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MAGEC1 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MAJIN | c.363T>A p.S121R | Missense Mutation (SNP) | VAF 90/458 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MAML3 | c.1346del p.G449Vfs*73 | Frame Shift Del (DEL) | VAF 85/397 reads (21%) | called by pindel, varscan2
- MAMSTR | c.382C>A p.P128T (on ENST00000318083 / NM_001130915.2; = p.P25T on NM_182574.2) | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MAS1L | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAZ | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MBL2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBP | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MDK | c.406+1G>A p.X136_splice | Splice Site (SNP) | VAF 76/344 reads (22%) | called by muse, varscan2
- MED12L | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED12L | c.2465A>C p.Y822S | Missense Mutation (SNP) | VAF 179/470 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MGAM2 | c.1427G>T p.W476L | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINAR1 | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MIOS | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 100/389 reads (26%) | called by muse, mutect2, varscan2
- MLLT6 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MRC2 | c.3077G>C p.S1026T | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH1 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 85/742 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MS4A3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2
- MS4A3 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MTBP | c.1942T>A p.F648I | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTDH | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTG2 | c.204G>T p.L68= | Splice Region (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2
- MTMR4 | c.1341del p.H448Tfs*49 | Frame Shift Del (DEL) | VAF 46/241 reads (19%) | called by mutect2, pindel, varscan2
- MTNR1A | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 109/836 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC12 | c.13735G>C p.E4579Q (on ENST00000379442; = p.E4436Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 324/4384 reads (7%) | SIFT deleterious (0.02); called by muse, mutect2
- MUC12 | c.14414C>A p.P4805Q (on ENST00000379442; = p.P4662Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 170/1015 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MUC16 | c.37063A>T p.T12355S | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC17 | c.12754C>A p.L4252I | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MUC19 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- MUC7 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MUTYH | c.883A>T p.S295C | Missense Mutation (SNP) | VAF 229/725 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- MYCN | c.1112G>T p.S371I | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYH15 | c.5317G>T p.E1773* | Nonsense Mutation (SNP) | VAF 101/422 reads (24%) | called by muse, mutect2, varscan2
- MYO7A | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYOC | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 90/716 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- NAT2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NCF1 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 140/659 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCKAP5 | c.3989C>A p.P1330H | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- NDUFAF4 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 238/736 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NF1 | c.4486_4500del p.L1496_S1500del (on ENST00000358273 / NM_001042492.3; = p.L1475_S1479del on NM_000267.3) | In Frame Del (DEL) | VAF 32/355 reads (9%) | called by mutect2, pindel
- NIBAN2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NOBOX | c.488dup p.S164Lfs*47 | Frame Shift Ins (INS) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- NOX4 | c.129T>G p.Y43* | Nonsense Mutation (SNP) | VAF 698/1008 reads (69%) | called by muse, mutect2, varscan2
- NPAS1 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NPAS4 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- NRCAM | c.2522G>T p.G841V (on ENST00000379028 / NM_001371124.1; = p.G825V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN1 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- NSRP1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NUDT22 | c.480+5G>C | Splice Region (SNP) | VAF 45/211 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.9331G>T p.E3111* | Nonsense Mutation (SNP) | VAF 77/237 reads (32%) | called by muse, mutect2, varscan2
- OGDHL | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OPRD1 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10D3 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR11H2 | c.43G>T p.E15* (on ENST00000556246; = p.E26* on NM_001197287.1) | Nonsense Mutation (SNP) | VAF 90/1860 reads (5%) | called by muse, mutect2
- OR2M5 | c.683T>A p.M228K | Missense Mutation (SNP) | VAF 190/710 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- OR2M5 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 188/708 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by mutect2, varscan2
- OR2M5 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 101/682 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR4A47 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- OR4C6 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 84/487 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OR52A5 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR52B2 | c.297T>A p.C99* | Nonsense Mutation (SNP) | VAF 121/506 reads (24%) | called by muse, mutect2, varscan2
- OR52N5 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 38/237 reads (16%) | called by muse, mutect2, varscan2
- OR5AP2 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR5J2 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- OR5T3 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- OTOGL | c.5330G>T p.C1777F (on ENST00000547103; = p.C1768F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- OVCH1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); called by muse, varscan2
- P2RY10 | c.360C>A p.S120R | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- P4HA3 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 114/673 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PAPPA | c.3137C>G p.A1046G | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAPPA2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PATL1 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 91/433 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDH15 | c.5491C>A p.P1831T | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA10 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 117/599 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCDHGA10 | c.306G>C p.Q102H | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PCDHGA5 | c.814G>C p.G272R | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCMTD1 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PDGFRA | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 174/1044 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFRA | c.1757G>T p.W586L | Missense Mutation (SNP) | VAF 145/609 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGD | c.520-1G>T p.X174_splice | Splice Site (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2
- PGD | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PGGT1B | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHKA1 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKHD1 | c.6019G>A p.G2007S | Missense Mutation (SNP) | VAF 106/1108 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.168); called by muse, mutect2
- PKHD1 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 137/661 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- PKHD1L1 | c.5887A>T p.S1963C | Missense Mutation (SNP) | VAF 140/879 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- PLXNB2 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMFBP1 | c.2709-2A>T p.X903_splice (on ENST00000537465; = p.X898_splice on NM_031293.3) | Splice Site (SNP) | VAF 64/266 reads (24%) | called by muse, varscan2
- POTEB3 | c.301T>C p.W101R | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- POTEG | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 166/2674 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.156); called by muse, mutect2
- POU3F1 | c.613C>G p.P205A | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PPIL4 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R26 | c.525A>T p.E175D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP1R32 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- PRCC | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRKD1 | c.1561A>T p.T521S | Missense Mutation (SNP) | VAF 174/699 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.014); called by muse, mutect2
- PRR16 | c.325C>A p.H109N (on ENST00000407149 / NM_001300783.2; = p.H86N on NM_016644.2) | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR23C | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PRR33 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PRR33 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PSD2 | c.878del p.E293Gfs*67 | Frame Shift Del (DEL) | VAF 82/430 reads (19%) | called by pindel, varscan2
- PSME4 | c.2341T>C p.F781L | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRC | c.1863G>T p.R621S | Missense Mutation (SNP) | VAF 181/689 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PTPRE | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PTPRH | c.1114G>T p.G372* | Nonsense Mutation (SNP) | VAF 46/168 reads (27%) | called by muse, varscan2
- PTPRZ1 | c.4868C>A p.S1623Y | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PUS7L | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PUS7L | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- PXDNL | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PYCR3 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- R3HDM2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 94/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RAB3IL1 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- RAD54L2 | c.3610G>T p.G1204C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- RALGAPA1 | c.4612G>T p.D1538Y | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMX | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- REG1B | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REM2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- REV3L | c.1360A>T p.N454Y | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RHO | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 83/387 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIMBP2 | c.2058A>T p.L686F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, varscan2
- RIPK2 | c.1559A>C p.Y520S | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF112 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RNF165 | c.744_745delinsA p.L249Wfs*4 | Frame Shift Del (DEL) | VAF 51/405 reads (13%) | called by pindel, varscan2*
- ROR2 | c.2268C>A p.N756K | Missense Mutation (SNP) | VAF 85/291 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RP1L1 | c.5933A>T p.E1978V | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RPA1 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RSPO2 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 156/488 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RTL1 | c.2304C>A p.S768R | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RTL1 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RTL3 | c.946T>C p.F316L | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RTL5 | c.1668A>T p.R556S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- RYR1 | c.12124C>A p.Q4042K | Missense Mutation (SNP) | VAF 235/500 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SACS | c.3088G>A p.V1030M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SAMD14 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCGN | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SCML4 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | called by muse, varscan2
- SCUBE3 | c.1313-1G>C p.X438_splice | Splice Site (SNP) | VAF 81/300 reads (27%) | called by muse, mutect2, varscan2
- SDK1 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 150/659 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK2 | c.2326G>T p.G776W | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERINC2 | c.611-1G>T p.X204_splice (on ENST00000373709 / NM_178865.5; = p.X208_splice on NM_018565.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1300G>T p.A434S (on ENST00000308713 / NM_001114099.3; = p.A364S on NM_012410.4) | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SF3B2 | c.1665G>C p.E555D | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SH3TC2 | c.3649G>T p.G1217C | Missense Mutation (SNP) | VAF 157/759 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIGLEC8 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SIM1 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC12A5 | c.1331C>G p.S444C (on ENST00000454036 / NM_001134771.2; = p.S421C on NM_020708.5) | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC28A2 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 138/451 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SLC28A2 | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC35A2 | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC35A2 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC45A2 | c.1529C>A p.T510K | Missense Mutation (SNP) | VAF 159/824 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SLC4A3 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC4A8 | c.1849del p.A617Qfs*42 | Frame Shift Del (DEL) | VAF 95/410 reads (23%) | called by mutect2, pindel, varscan2
- SLC8B1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SLC9A1 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SLCO1A2 | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SLCO1B3 | c.276C>A p.H92Q | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.3584G>T p.G1195V | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMAP2 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SMG9 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 164/393 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SNRNP40 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2
- SNTG1 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 83/590 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SNTG1 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 82/591 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SNTG2 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- SORCS3 | c.1600C>A p.L534M | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.757); called by muse, mutect2
- SP100 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SPATA17 | c.566G>T p.W189L | Missense Mutation (SNP) | VAF 63/434 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A6 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 160/1186 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SPATS1 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 144/634 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRGAP3 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 96/633 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SRP72 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STAMBPL1 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- SWT1 | c.21_22dup p.G8Vfs*39 | Frame Shift Ins (INS) | VAF 40/408 reads (10%) | called by pindel, varscan2
- SWT1 | c.23_24insT p.K9Efs*19 | Frame Shift Ins (INS) | VAF 51/473 reads (11%) | called by mutect2, varscan2*
- SYNE3 | c.2538G>C p.Q846H | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TAOK3 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 73/440 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TDRD9 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, varscan2
- TEP1 | c.6607G>T p.G2203* | Nonsense Mutation (SNP) | VAF 89/453 reads (20%) | called by muse, mutect2, varscan2
- THAP11 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TINAG | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 138/617 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIPRL | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 107/507 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TLR7 | c.926G>T p.W309L | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TMEM131L | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM132B | c.2894C>G p.S965* | Nonsense Mutation (SNP) | VAF 109/525 reads (21%) | called by muse, mutect2, varscan2
- TMEM132C | c.1629G>T p.W543C | Missense Mutation (SNP) | VAF 106/388 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM151A | c.962C>A p.A321D | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM260 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM33 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TMEM51 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TOMM20L | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TRDMT1 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TREML1 | c.731C>G p.T244S | Missense Mutation (SNP) | VAF 175/740 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TRIM43B | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 99/536 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM49B | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 107/1358 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TRIM58 | c.509T>G p.I170S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM64C | c.285T>G p.H95Q | Missense Mutation (SNP) | VAF 138/1176 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIO | c.866G>T p.S289I | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TRIP12 | c.3271G>T p.G1091C | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- TRIP12 | c.2386A>T p.I796F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRMT44 | c.1124G>T p.S375I | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- TRPC6 | c.2645G>A p.G882E | Missense Mutation (SNP) | VAF 1472/1884 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- TRPM8 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 83/638 reads (13%) | called by muse, mutect2, varscan2
- TSC22D2 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC27 | c.1918A>T p.T640S | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, varscan2
- TTC29 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 123/496 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TTC37 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TTC37 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 123/575 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- TTN | c.47776C>A p.P15926T (on ENST00000591111; = p.P8502T on NM_003319.4) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNRD3 | c.1415A>T p.Y472F | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2
- TYW1B | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 95/592 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- UBXN2A | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- UGT2B28 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1974G>T p.Q658H | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- UNC80 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.275); called by muse, mutect2
- UNC80 | c.6529C>G p.P2177A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UQCRC1 | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- USH2A | c.11606A>T p.D3869V | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- USH2A | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP29 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- VWA5B2 | c.3715C>A p.P1239T | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR49 | c.308C>A p.S103Y (on ENST00000308378 / NM_001366158.1; = p.S444Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 191/556 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- WDR87 | c.3628G>A p.V1210I | Missense Mutation (SNP) | VAF 250/538 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- WIPF1 | c.1363T>A p.Y455N | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK1 | c.3964G>C p.A1322P (on ENST00000315939 / NM_018979.4; = p.A1075P on NM_014823.3) | Missense Mutation (SNP) | VAF 181/846 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XAF1 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 181/513 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XXYLT1 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YY1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, varscan2
- YY2 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB8A | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ZMYND10 | c.873+1G>C p.X291_splice | Splice Site (SNP) | VAF 131/477 reads (27%) | called by muse, mutect2, varscan2
- ZNF365 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF451 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 96/520 reads (18%) | called by muse, mutect2, varscan2
- ZNF454 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF479 | c.1065T>A p.C355* | Nonsense Mutation (SNP) | VAF 88/407 reads (22%) | called by muse, mutect2, varscan2
- ZNF516 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 86/459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF534 | c.1366T>C p.C456R (on ENST00000332323 / NM_001143939.3; = p.C443R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF585B | c.830_832delinsTT p.Q277Lfs*9 | Frame Shift Del (DEL) | VAF 87/264 reads (33%) | called by pindel, varscan2*
- ZNF592 | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 184/621 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF639 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2
- ZNF649 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF727 | c.128T>A p.L43* | Nonsense Mutation (SNP) | VAF 77/314 reads (25%) | called by muse, mutect2, varscan2
- ZNF808 | c.1927A>G p.R643G | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ABCA5 | c.4497C>G p.V1499= | Silent (SNP) | VAF 60/496 reads (12%) | catalogued as COSV67017155; called by muse, mutect2, varscan2
- ABCA8 | c.6G>A p.R2= | Silent (SNP) | VAF 78/336 reads (23%) | catalogued as COSV52197599; called by muse, varscan2
- ABCB11 | c.2037G>A p.A679= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs776223452, COSV55590331; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABHD12B | c.75C>A p.A25= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- ACOD1 | c.921G>A p.K307= | Silent (SNP) | VAF 131/382 reads (34%) | called by muse, mutect2, varscan2
- ACTN2 | c.1395G>C p.A465= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as COSV63974194; called by muse, mutect2, varscan2
- ADAMTS16 | c.120G>C p.P40= | Silent (SNP) | VAF 99/530 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.2709C>A p.A903= | Silent (SNP) | VAF 141/645 reads (22%) | called by muse, mutect2, varscan2
- ADCY6 | c.3339C>T p.V1113= | Silent (SNP) | VAF 46/235 reads (20%) | called by muse, mutect2, varscan2
- ADCY9 | c.448C>T p.L150= | Silent (SNP) | VAF 46/342 reads (13%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4788C>A p.T1596= | Silent (SNP) | VAF 76/148 reads (51%) | called by muse, mutect2, varscan2
- ADRA1A | c.822G>C p.L274= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as rs767363143, COSV99371519; called by muse, mutect2, varscan2
- AFF3 | c.1866G>T p.P622= | Silent (SNP) | VAF 47/215 reads (22%) | catalogued as COSV57862237; called by muse, mutect2, varscan2
- AHNAK2 | c.8550C>T p.P2850= | Silent (SNP) | VAF 68/314 reads (22%) | called by muse, varscan2
- ALLC | c.1068G>T p.G356= | Silent (SNP) | VAF 73/257 reads (28%) | called by muse, mutect2, varscan2
- ANTXRL | c.1212G>T p.P404= | Silent (SNP) | VAF 40/168 reads (24%) | called by muse, mutect2, varscan2
- ANXA4 | c.234C>T p.F78= | Silent (SNP) | VAF 81/427 reads (19%) | catalogued as rs745848655; called by muse, mutect2, varscan2
- ARFGAP1 | c.1149C>T p.G383= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs775620661, COSV62263495; called by muse, mutect2, varscan2
- ARSI | c.657C>A p.I219= | Silent (SNP) | VAF 79/322 reads (25%) | catalogued as COSV60817988; called by muse, mutect2, varscan2
- ATP2B2 | c.960A>G p.L320= (on ENST00000352432; = p.L331= on NM_001001331.4) | Silent (SNP) | VAF 105/617 reads (17%) | called by muse, mutect2, varscan2
- B3GAT2 | c.612C>A p.V204= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- BBS7 | c.1830C>T p.H610= | Silent (SNP) | VAF 36/322 reads (11%) | called by muse, mutect2, varscan2
- BIN1 | c.1647G>A p.V549= (on ENST00000316724 / NM_001320642.1; = p.V410= on NM_004305.4) | Silent (SNP) | VAF 64/461 reads (14%) | called by muse, mutect2, varscan2
- BUB1 | c.2895G>A p.K965= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV57066271; called by muse, mutect2, varscan2
- CADPS | c.147G>T p.G49= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, varscan2
- CAMK2B | c.474C>T p.F158= | Silent (SNP) | VAF 104/437 reads (24%) | catalogued as rs1367462372, COSV51659321; called by muse, mutect2, varscan2
- CAPZA2 | c.843A>G p.K281= | Silent (SNP) | VAF 55/222 reads (25%) | called by muse, mutect2, varscan2
- CBL | c.561G>T p.A187= | Silent (SNP) | VAF 121/478 reads (25%) | catalogued as COSV50644078; called by muse, mutect2, varscan2
- CCDC80 | c.780C>A p.V260= | Silent (SNP) | VAF 173/772 reads (22%) | called by muse, mutect2, varscan2
- CCHCR1 | c.2199A>G p.A733= | Silent (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
342 further variants in this file (0 protein-altering or splice-affecting, 198 silent, 144 other) are not listed here.
